Somatic mutation profile of tumor specimen TCGA-A6-6781-01A (aliquot TCGA-A6-6781-01A-22D-A270-10) from TCGA case TCGA-A6-6781, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 43.4 years (15,842 days).
Specimen TCGA-A6-6781-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7af7243-717e-45bb-a9b6-7cd074c1c548.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6781-10A (Blood Derived Normal), aliquot TCGA-A6-6781-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f307d7c1-9775-4f7b-8b20-2e30299e2743

The open-access MAF lists 2,548 somatic variants for this specimen: 1,839 protein-altering or splice-affecting, 530 silent, 179 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,312, Silent 530, Frame Shift Del 338, Frame Shift Ins 74, Intron 69, Nonsense Mutation 67, 3'UTR 61, Splice Site 20, RNA 20, Splice Region 15, In Frame Del 12, 5'UTR 11.

Variants (750 of 2,548; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DOK7 | c.1263del p.S422Hfs*34 | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | catalogued as rs606231129; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DSG2 | c.2533del p.I845* | Frame Shift Del (DEL) | VAF 23/96 reads (24%) | catalogued as rs1375081885; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ESCO2 | c.1111dup p.T371Nfs*32 | Frame Shift Ins (INS) | VAF 22/103 reads (21%) | catalogued as rs80359859; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- GAA | c.2242del p.E748Rfs*16 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as rs777275355, CM082763, CM128388, CM970554; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- GBE1 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369574719; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- GJB1 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); catalogued as rs139643362, CM1211027, CM960753, COSV62139490; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLDC | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as rs386833517, CM061029, COSV58675961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIF1A | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs672601368, CM150187, CM157166, COSV57482056; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- MLH1 | c.588del p.K196Nfs*6 | Frame Shift Del (DEL) | VAF 30/140 reads (21%) | catalogued as rs63751653, CM151408, COSV51624461; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 14/58 reads (24%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.3376C>T p.Q1126* | Nonsense Mutation (SNP) | VAF 12/71 reads (17%) | catalogued as rs1555614947, CM143375, COSV62191417; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHS2 | c.467dup p.L156Ffs*11 | Frame Shift Ins (INS) | VAF 32/136 reads (24%) | catalogued as rs528833893; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- SACS | c.8612dup p.L2871Ffs*29 | Frame Shift Ins (INS) | VAF 19/88 reads (22%) | catalogued as rs1057517212; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SCN1A | c.4942C>T p.R1648C (on ENST00000303395 / NM_001202435.3; = p.R1637C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918791, CM024311, COSV57658439; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SMARCA4 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281875227, CM122492, COSV100759471, COSV60785471; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.842del p.P281Rfs*6 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | catalogued as rs121913321; ClinVar: pathogenic; called by pindel, varscan2*
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- USH2A | c.11156G>A p.R3719H | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs527236139, CM148283, COSV56321550; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.8890del p.W2964Gfs*10 | Frame Shift Del (DEL) | VAF 28/157 reads (18%) | catalogued as rs786205116; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- A2M | c.2579T>C p.V860A | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100588574; called by muse, mutect2
- AAMP | c.44del p.P15Hfs*5 | Frame Shift Del (DEL) | VAF 50/200 reads (25%) | catalogued as rs751284215; called by mutect2, varscan2
- AARS1 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs202099051, COSV55745853; called by muse, mutect2, varscan2
- ABCA1 | c.5966G>A p.G1989D | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101036758; called by muse, varscan2
- ABCA13 | c.2842A>G p.I948V | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs779473888, COSV70025475; called by muse, mutect2, varscan2
- ABCA2 | c.6014-2A>C p.X2005_splice (on ENST00000614293; = p.X1975_splice on NM_001606.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 22/112 reads (20%) | catalogued as COSV55796682; called by muse, mutect2, varscan2
- ABCA6 | c.917dup p.L306Ffs*44 | Frame Shift Ins (INS) | VAF 84/392 reads (21%) | catalogued as rs750282619; called by mutect2, varscan2
- ABCB8 | c.1387G>A p.V463I (on ENST00000297504 / NM_001282291.2; = p.V446I on NM_007188.5) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370506479; called by muse, mutect2, varscan2
- ABCC1 | c.2047G>A p.G683R | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766665700, COSV60679093; called by muse, mutect2, varscan2
- ABCF3 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200451515, COSV53055025; called by muse, mutect2, varscan2
- ABHD18 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 27/98 reads (28%) | catalogued as rs773100732, COSV66292887; called by muse, mutect2, varscan2
- ABL2 | c.3481G>A p.G1161R (on ENST00000502732 / NM_007314.4; = p.G1146R on NM_005158.5) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1467885528, COSV61010680; called by muse, mutect2, varscan2
- AC004593.2 | c.1541del p.P514Lfs*6 | Frame Shift Del (DEL) | VAF 24/145 reads (17%) | catalogued as COSV56099196; called by mutect2, pindel, varscan2
- AC068580.4 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52586909; called by muse, mutect2, varscan2
- AC090517.4 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as COSV50995640; called by muse, mutect2, varscan2
- ACACB | c.4192del p.L1398Sfs*26 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as rs1565953344, COSV58128358; called by mutect2, pindel, varscan2
- ACADL | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.249); catalogued as COSV52051969; called by muse, mutect2, varscan2
- ACAP3 | c.1812C>T p.R604= | Splice Region (SNP) | VAF 19/72 reads (26%) | catalogued as COSV57639490; called by muse, mutect2, varscan2
- ACIN1 | c.4018C>T p.R1340C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV52972567; called by muse, mutect2, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 27/129 reads (21%) | catalogued as rs879396950, COSV52972585; called by pindel, varscan2
- ACKR3 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1325541874, COSV56020269; called by muse, mutect2, varscan2
- ACKR3 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs771402831, COSV56020278; called by muse, mutect2, varscan2
- ACOT11 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194863911, COSV56362801; called by muse, varscan2
- ACOX3 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100711899; called by muse, mutect2, varscan2
- ACP5 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs745604493, COSV54535093; called by muse, mutect2, varscan2
- ACP7 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs753445095, COSV58698145; called by muse, mutect2, varscan2
- ACSL6 | c.524T>C p.V175A (on ENST00000379240; = p.V200A on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57302155; called by muse, mutect2, varscan2
- ACSL6 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV99733188; called by muse, mutect2, varscan2
- ACTL6A | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.68); catalogued as rs773240025, COSV66998577; called by muse, mutect2, varscan2
- ACTL9 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100185539, COSV61004558; called by muse, mutect2, varscan2
- ACTN1 | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs371440985, COSV51997373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM10 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs752797397, COSV53048879; called by muse, mutect2, varscan2
- ADAM22 | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55968532; called by muse, mutect2, varscan2
- ADAM9 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV65946534; called by muse, mutect2, varscan2
- ADAMDEC1 | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99835958; called by muse, mutect2, varscan2
- ADAMTS13 | c.3158C>T p.A1053V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.096); catalogued as rs373530345; called by muse, mutect2, varscan2
- ADAMTS7 | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs200298365; called by mutect2, varscan2
- ADAMTS7 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as COSV66305610; called by muse, mutect2, varscan2
- ADAMTS7 | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.046); catalogued as COSV66305615; called by muse, mutect2, varscan2
- ADAMTS8 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1031384898, COSV57290808; called by muse, mutect2, varscan2
- ADAMTSL2 | c.512G>A p.C171Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63203068; called by muse, mutect2, varscan2
- ADCY5 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59193338; called by muse, mutect2, varscan2
- ADD1 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs913024832, COSV53265909; called by muse, mutect2, varscan2
- ADGB | c.4409C>T p.A1470V | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs747324258, COSV58846630; called by muse, mutect2, varscan2
- ADGRA1 | c.1371del p.S458Afs*79 | Frame Shift Del (DEL) | VAF 20/116 reads (17%) | catalogued as rs1202605317; called by mutect2, pindel, varscan2
- ADGRB1 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60091168; called by muse, mutect2, varscan2
- ADGRB1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60091183; called by muse, mutect2, varscan2
- ADGRD1 | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99894742; called by muse, mutect2, varscan2
- ADGRD2 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1274838000, COSV58339191; called by muse, mutect2, varscan2
- ADGRE5 | c.1735C>T p.R579C (on ENST00000242786 / NM_078481.4; = p.R486C on NM_001784.5) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54390283; called by muse, mutect2, varscan2
- ADSL | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 21/87 reads (24%) | catalogued as COSV53406376; called by muse, mutect2, varscan2
- AFF4 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs780771766, COSV54793422; called by muse, mutect2, varscan2
- AGAP3 | c.1402G>A p.A468T (on ENST00000622464; = p.A504T on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1206414003, COSV68242962; called by muse, varscan2
- AGAP3 | c.1463G>A p.R488H (on ENST00000622464; = p.R524H on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs925378481, COSV68242968; called by muse, varscan2
- AGBL5 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747191439, COSV59935370; called by muse, mutect2, varscan2
- AHSG | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV56606886; called by muse, mutect2, varscan2
- AIFM3 | c.1264G>A p.V422I | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.472); catalogued as rs774742086, COSV53150302; called by muse, mutect2, varscan2
- AJM1 | c.2209T>G p.S737A | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99915553; called by muse, mutect2, varscan2
- AKAP13 | c.6031C>T p.R2011C (on ENST00000394518 / NM_007200.5; = p.R2015C on NM_006738.6) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs934979969, COSV100773407; called by muse, mutect2, varscan2
- ALG13 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767153325, COSV52634625, COSV99322475; called by muse, mutect2, varscan2
- ALOX15B | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs372320255; called by muse, mutect2, varscan2
- ALPK3 | c.2010G>T p.Q670H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV51928387, COSV51940020; called by muse, mutect2, varscan2
- ALS2 | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs747774956, COSV51889758; called by muse, mutect2, varscan2
- AMER3 | c.611del p.P204Rfs*62 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as COSV100365971, COSV58465768; called by mutect2, pindel
- AMOT | c.3074C>A p.A1025D (on ENST00000371959 / NM_001113490.1; = p.A616D on NM_133265.3) | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV59059812; called by muse, varscan2
- AMOTL1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.098); catalogued as rs371806495, COSV54414848; called by muse, mutect2, varscan2
- AMPD2 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.19); catalogued as COSV56645918; called by muse, mutect2, varscan2
- ANAPC1 | c.4004G>A p.R1335H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs1159635391; called by muse, mutect2, varscan2
- ANKMY2 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs768714189, COSV100186992; called by muse, mutect2, varscan2
- ANKRD11 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776780527, COSV56376470; called by muse, mutect2, varscan2
- ANKRD53 | c.1211A>G p.Q404R | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.828); catalogued as COSV55536182; called by muse, mutect2, varscan2
- ANKS1A | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64458497; called by muse, mutect2, varscan2
- ANKS6 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs780586485, COSV62048625; called by muse, mutect2, varscan2
- ANO5 | c.898dup p.I300Nfs*36 | Frame Shift Ins (INS) | VAF 22/84 reads (26%) | catalogued as rs1383346134; called by mutect2, pindel, varscan2
- ANO9 | c.1282C>T p.Q428* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | catalogued as COSV60447955; called by muse, mutect2, varscan2
- ANXA1 | c.801C>T p.I267= | Splice Region (SNP) | VAF 7/50 reads (14%) | catalogued as rs757586479, COSV57410254; called by muse, mutect2, varscan2
- AP000721.1 | c.113T>C p.M38T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1163739348, COSV100029278; called by muse, mutect2, varscan2
- AP2B1 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 36/137 reads (26%) | catalogued as COSV51996586; called by muse, mutect2, varscan2
- AP3B2 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV55605940; called by muse, mutect2, varscan2
- APC | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as rs372416031, COSV57346229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC2 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs148440924; called by muse, mutect2, varscan2
- APOA5 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV57062007, COSV57064010; called by muse, mutect2, varscan2
- APOBEC1 | c.207del p.K69Nfs*12 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | catalogued as rs753365818; called by mutect2, pindel, varscan2
- AQP10 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV61474316; called by muse, mutect2, varscan2
- AQP8 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780774514, COSV54843977; called by muse, mutect2, varscan2
- ARAP3 | c.1171del p.Q391Nfs*24 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs748757285; called by mutect2, pindel, varscan2
- ARHGAP19 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs201761042, COSV57391210; called by muse, mutect2, varscan2
- ARHGAP23 | c.2011G>A p.A671T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as rs1407438959; called by muse, mutect2, varscan2
- ARHGAP27 | c.2260C>T p.L754F (on ENST00000428638 / NM_001282290.1; = p.L413F on NM_199282.3) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65356925; called by muse, varscan2
- ARHGAP28 | c.1065del p.F355Lfs*8 (on ENST00000383472 / NM_001366230.1; = p.F196Lfs*8 on NM_001010000.3) | Frame Shift Del (DEL) | VAF 28/138 reads (20%) | catalogued as rs1567977926, COSV51634082; called by mutect2, pindel, varscan2
- ARHGAP31 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765209939, COSV51794256; called by muse, mutect2, varscan2
- ARHGAP33 | c.1961del p.G654Efs*34 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | catalogued as rs1378832725; called by mutect2, pindel, varscan2
- ARHGAP35 | c.4096A>G p.K1366E | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV68328891; called by muse, mutect2, varscan2
- ARHGAP4 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782767558, COSV63130534; called by muse, mutect2, varscan2
- ARHGAP45 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 37/155 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV99565465; called by muse, mutect2, varscan2
- ARHGEF10L | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as COSV63414767; called by muse, mutect2, varscan2
- ARHGEF10L | c.2176G>A p.G726S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1292671192, COSV51426980; called by muse, mutect2, varscan2
- ARHGEF2 | c.1667G>A p.R556Q (on ENST00000361247 / NM_001162383.2; = p.R528Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV100560709, COSV58105714; called by muse, mutect2, varscan2
- ARHGEF26 | c.1532T>C p.I511T | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs775941680, COSV62843442; called by muse, mutect2, varscan2
- ARHGEF33 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101289771; called by muse, mutect2, varscan2
- ARHGEF40 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs753025691, COSV53877914; called by muse, mutect2, varscan2
- ARID5B | c.3310C>T p.Q1104* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV54414378, COSV99689389; called by muse, mutect2, varscan2
- ARMC4 | c.2908C>T p.R970C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as rs776293552, COSV59454922, COSV59461869; called by muse, mutect2, varscan2
- ARSG | c.914C>A p.P305Q | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV101477882, COSV101477889; called by muse, mutect2, varscan2
- ART1 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0.053); catalogued as rs750142725, COSV51702680; called by muse, varscan2
- ARVCF | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs767313095, COSV54264414; called by muse, mutect2, varscan2
- ASB2 | c.1385A>G p.Y462C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100279281; called by muse, mutect2, varscan2
- ASH1L | c.2134del p.R712Efs*23 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs1558150870; called by mutect2, varscan2
- ASPHD1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58096738; called by muse, mutect2, varscan2
- ASPM | c.4849C>T p.R1617* | Nonsense Mutation (SNP) | VAF 32/167 reads (19%) | catalogued as rs772050241, CM133317, COSV54123536; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ASPM | c.1780A>G p.T594A | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54123575; called by muse, mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 14/91 reads (15%) | catalogued as rs1558707706; called by mutect2, pindel, varscan2
- ATG9A | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV63444785; called by muse, mutect2, varscan2
- ATIC | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as COSV52691504; called by muse, mutect2, varscan2
- ATP10B | c.2548C>T p.R850W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs754741809, COSV59142627; called by muse, mutect2, varscan2
- ATP10D | c.142G>T p.G48* | Nonsense Mutation (SNP) | VAF 27/118 reads (23%) | catalogued as COSV99905415; called by muse, mutect2, varscan2
- ATP12A | c.342del p.F115Sfs*28 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as rs35191129; called by mutect2, pindel, varscan2
- ATP13A2 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as rs142699829; called by muse, mutect2, varscan2
- ATP13A3 | c.3341dup p.L1114Ffs*17 | Frame Shift Ins (INS) | VAF 102/446 reads (23%) | catalogued as rs1265328796; called by mutect2, varscan2
- ATP2A1 | c.1712del p.P571Rfs*21 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | catalogued as rs772363145; called by mutect2, pindel, varscan2
- ATP2B1 | c.2620G>A p.A874T | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs570457928, COSV53803084, COSV99666296; called by muse, mutect2, varscan2
- ATP2B1 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV53803103; called by muse, mutect2, varscan2
- ATP2B2 | c.1780G>A p.V594M (on ENST00000352432; = p.V560M on NM_001683.5) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs199991046, COSV100660611, COSV59487900, COSV59490206; called by muse, mutect2, varscan2
- ATP5F1C | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 101/417 reads (24%) | catalogued as rs1436478284, COSV59620786; called by muse, mutect2, varscan2
- ATP6V1H | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.069); catalogued as rs770965453, COSV100778731, COSV62216636; called by muse, mutect2, varscan2
- ATP8A1 | c.1631T>C p.L544P | Missense Mutation (SNP) | VAF 72/322 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52527326; called by muse, mutect2, varscan2
- ATP9A | c.1291del p.Q431Sfs*22 | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | catalogued as COSV58766683; called by mutect2, pindel, varscan2
- ATP9B | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.756); catalogued as COSV56944657; called by muse, mutect2, varscan2
- AUTS2 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV100715966; called by muse, mutect2
- AVIL | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs769888107, COSV57680157; called by muse, mutect2, varscan2
- AXDND1 | c.2227C>T p.R743* | Nonsense Mutation (SNP) | VAF 56/244 reads (23%) | catalogued as rs771074994, COSV62647551, COSV62648978; called by muse, mutect2, varscan2
- AXL | c.874del p.H292Ifs*5 | Frame Shift Del (DEL) | VAF 13/86 reads (15%) | catalogued as rs778012871; called by mutect2, pindel, varscan2
- AXL | c.2351G>A p.R784Q (on ENST00000301178 / NM_021913.5; = p.R775Q on NM_001699.6) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs201956398, COSV56563180; called by muse, mutect2, varscan2
- BAG3 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV64841557; called by muse, mutect2, varscan2
- BAHCC1 | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as COSV57022197; called by muse, mutect2
- BARX1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV99560965; called by muse, mutect2
- BASP1 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.291); catalogued as COSV100493659; called by muse, mutect2
- BAZ2A | c.5558C>T p.T1853I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV51639393; called by muse, mutect2, varscan2
- BCAR3 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1188864980, COSV53080058; called by muse, mutect2, varscan2
- BCL2L11 | c.574C>T p.R192C (on ENST00000393256 / NM_138621.5; = p.R132C on NM_006538.5) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758817904, COSV58027602; called by muse, mutect2, varscan2
- BCL9 | c.2605C>T p.H869Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV52340267; called by muse, mutect2, varscan2
- BCLAF1 | c.1694T>C p.L565S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV62140042; called by muse, mutect2, varscan2
- BEND3 | c.2073dup p.E692Rfs*21 | Frame Shift Ins (INS) | VAF 26/109 reads (24%) | catalogued as rs782172473; called by mutect2, pindel, varscan2
- BEST3 | c.1332del p.R445Gfs*40 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs779566914, COSV58300788; called by mutect2, pindel, varscan2
- BHLHE22 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as COSV100417679; called by muse, mutect2
- BIRC6 | c.6899G>A p.R2300H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs768271303, COSV70194919; called by muse, mutect2, varscan2
- BMF | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV55018504; called by muse, mutect2, varscan2
- BMP1 | c.2576A>T p.E859V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as COSV60527660; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as rs763134487; called by mutect2, varscan2
- BRD4 | c.3629C>T p.P1210L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs1489035830, COSV54581611; called by muse, mutect2, varscan2
- BRF1 | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.102); catalogued as COSV59265557; called by muse, mutect2, varscan2
- BRIP1 | c.2054A>C p.Q685P | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51993186; called by muse, mutect2, varscan2
- BRPF1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs750391785, COSV57402894; called by muse, mutect2, varscan2
- BRSK2 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57539457; called by muse, mutect2, varscan2
- BRWD3 | c.3061T>C p.S1021P | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV64743359; called by muse, mutect2, varscan2
- BSCL2 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs878855171, COSV54014601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTAF1 | c.4415G>C p.S1472T | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56429215; called by muse, mutect2, varscan2
- BTBD2 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55307246; called by muse, mutect2
- BTNL3 | c.1200del p.S401Afs*7 | Frame Shift Del (DEL) | VAF 34/158 reads (22%) | catalogued as rs757227190; called by mutect2, pindel, varscan2
- C11orf24 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs543093269, COSV100422528; called by muse, mutect2, varscan2
- C11orf42 | c.685A>G p.N229D | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV56409233; called by muse, mutect2, varscan2
- C14orf180 | c.135dup p.S46Lfs*39 | Frame Shift Ins (INS) | VAF 24/221 reads (11%) | catalogued as rs761345073; called by mutect2, varscan2
- C14orf93 | c.1497_1499del p.E501del | In Frame Del (DEL) | VAF 24/118 reads (20%) | catalogued as rs1431730242; called by pindel, varscan2
- C15orf39 | c.1038del p.S347Lfs*30 | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | catalogued as rs774177293; called by mutect2, pindel, varscan2
- C16orf54 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs796580121, COSV61476544; called by muse, mutect2, varscan2
- C1GALT1 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56178587, COSV56178990; called by muse, mutect2, varscan2
- C20orf27 | c.53C>T p.A18V (on ENST00000379772 / NM_001258429.2; = p.A43V on NM_001039140.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs41279396, COSV53923063; called by muse, mutect2, varscan2
- C2orf76 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs200764717; called by muse, mutect2, varscan2
- C4BPA | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.734); catalogued as rs762693425, COSV65535547; called by muse, mutect2, varscan2
- C6orf136 | c.763C>T p.R255W (on ENST00000376473 / NM_001109938.3; = p.R121W on NM_145029.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289606411, COSV99527841; called by muse, mutect2
- C6orf141 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.386); catalogued as COSV100965956; called by muse, mutect2
- C7orf31 | c.358del p.S120Vfs*9 | Frame Shift Del (DEL) | VAF 102/475 reads (21%) | catalogued as rs750735753; called by mutect2, pindel, varscan2
- C7orf57 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373360459; called by muse, mutect2, varscan2
- C8B | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs760472969, COSV100980740; called by muse, mutect2, varscan2
- CA12 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs1386605503, COSV99458059; called by muse, mutect2, varscan2
- CA7 | c.449dup p.L150Ffs*58 | Frame Shift Ins (INS) | VAF 30/107 reads (28%) | catalogued as rs1567506914; called by mutect2, varscan2
- CABIN1 | c.5017C>T p.R1673C | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.226); catalogued as rs749933147, COSV54076896; called by muse, mutect2, varscan2
- CABP4 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs1451789307, COSV56884787; called by muse, mutect2, varscan2
- CABS1 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs762044516, COSV56732853; called by muse, mutect2, varscan2
- CACHD1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 72/299 reads (24%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.921); catalogued as rs1329242081, COSV51547183; called by muse, varscan2
- CACNA1B | c.4352G>A p.R1451Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1289601418, COSV53111739, COSV99499705; called by muse, mutect2, varscan2
- CACNA1D | c.5371C>T p.H1791Y (on ENST00000350061 / NM_001128840.3; = p.H1811Y on NM_000720.4) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.055); catalogued as COSV55435994; called by muse, mutect2, varscan2
- CACNA1E | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760975849, COSV62380904; called by muse, mutect2, varscan2
- CACNA1F | c.3179G>A p.R1060Q | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs5906755, COSV59902745; called by muse, mutect2, varscan2
- CACNA1G | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1373767246, COSV61719733; called by muse, mutect2, varscan2
- CACNA1G | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs970742328, COSV61719744; called by muse, mutect2, varscan2
- CACNA1S | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs758594181, COSV62935565, COSV62944526; ClinVar: uncertain significance; called by muse, varscan2
- CACNA2D3 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55509602; called by muse, mutect2, varscan2
- CACNG5 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs142426129, COSV50054657; called by muse, mutect2, varscan2
- CAD | c.5702C>A p.P1901H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV99254753; called by muse, mutect2
- CADPS | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs182039177, COSV51865292; called by muse, mutect2, varscan2
- CAMSAP3 | c.2644C>T p.R882W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV50330612; called by muse, mutect2, varscan2
- CAMTA1 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs745719073, COSV57885227; called by mutect2, varscan2
- CAPN14 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs764024066, COSV67289649; called by muse, mutect2, varscan2
- CAPN5 | c.1607G>A p.R536Q (on ENST00000456580; = p.R496Q on NM_004055.5) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs563895448, CM142317, COSV53685228; called by muse, mutect2, varscan2
- CARD8 | c.340dup p.D114Gfs*34 (on ENST00000651546 / NM_001184900.3; = p.D64Gfs*34 on NM_014959.5 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 24/98 reads (24%) | catalogued as rs770149864; called by mutect2, varscan2
- CARHSP1 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs368082559; called by muse, mutect2, varscan2
- CARMIL1 | c.4011G>T p.Q1337H | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100277382; called by muse, mutect2, varscan2
- CARNS1 | c.2212G>T p.G738C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57047168; called by muse, mutect2, varscan2
- CASKIN2 | c.2182del p.Q728Rfs*74 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs751998890, COSV100051067; called by mutect2, varscan2
- CASKIN2 | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376422585; called by muse, mutect2, varscan2
- CASQ1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.231); catalogued as COSV63623853; called by muse, mutect2, varscan2
- CASR | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs764023058, COSV56133705, COSV99948869; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASR | c.1802G>A p.R601H (on ENST00000490131; = p.R678H on NM_000388.4) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as rs1278025825, CM165796, COSV56139931, COSV56142619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASZ1 | c.4382G>A p.R1461H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs747304331, COSV65455655; called by muse, mutect2, varscan2
- CBFA2T3 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs1469343109, COSV51922472; called by muse, mutect2
- CBX4 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53964132; called by muse, mutect2, varscan2
- CCDC106 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.197); catalogued as rs200120422; called by muse, mutect2, varscan2
- CCDC113 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV99540827; called by muse, mutect2, varscan2
- CCDC130 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs1386642332, COSV50003552; called by muse, mutect2, varscan2
- CCDC136 | c.3143del p.K1048Sfs*3 | Frame Shift Del (DEL) | VAF 36/159 reads (23%) | catalogued as rs761237807; called by mutect2, varscan2
- CCDC182 | c.64del p.M22* | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | catalogued as rs1567992795; called by mutect2, pindel, varscan2
- CCDC24 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs763595255, COSV58842286; called by muse, mutect2, varscan2
- CCDC28B | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs201902661, COSV99356411, COSV99356456; called by muse, mutect2, varscan2
- CCDC71 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as COSV58909676; called by muse, mutect2, varscan2
- CCDC8 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs754734333, COSV56772049; called by muse, varscan2
- CCDC88B | c.3854G>A p.R1285H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756702849, COSV57264692; called by muse, mutect2, varscan2
- CCDC88C | c.5572C>T p.R1858W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs763090813, COSV57795739; called by muse, mutect2, varscan2
- CCNA1 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.146); catalogued as COSV55219692, COSV55221357; called by muse, mutect2, varscan2
- CCNF | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs753372697, COSV53537486; called by muse, mutect2, varscan2
- CCNL1 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs948726021, COSV55818059; called by muse, mutect2, varscan2
- CCNT2 | c.813G>T p.Q271H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.827); catalogued as COSV99750382; called by muse, mutect2, varscan2
- CCR2 | c.176G>C p.G59A | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52747463; called by muse, mutect2, varscan2
- CD101 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756924215, COSV56715644, COSV56715779; called by muse, mutect2, varscan2
- CD109 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs199660260, COSV54644411; called by muse, mutect2, varscan2
- CD19 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV61187649; called by muse, mutect2, varscan2
- CD1C | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as COSV100939371; called by muse, varscan2
- CD247 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs760895755, COSV62976678; called by muse, mutect2, varscan2
- CD79B | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148032848, COSV50077193, COSV50079859; called by muse, mutect2, varscan2
- CD93 | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99849061; called by muse, mutect2, varscan2
- CDAN1 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs373790041; called by muse, mutect2, varscan2
- CDC16 | c.1859C>T p.T620M | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.416); catalogued as rs373980044; called by muse, mutect2, varscan2
- CDCA4 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as rs1312795304, COSV60314883; called by muse, mutect2, varscan2
- CDH11 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.048); catalogued as rs767812673, COSV51750088; called by muse, mutect2, varscan2
- CDH23 | c.5116C>T p.R1706C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs759876454, COSV99819982; called by muse, mutect2, varscan2
- CDH24 | c.771del p.K258Sfs*36 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | catalogued as rs753422808; called by pindel, varscan2
- CDHR5 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as rs538514960, COSV57641051; called by muse, mutect2, varscan2
- CDHR5 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as rs764791491, COSV57641059; called by muse, mutect2, varscan2
- CDK5RAP3 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778005374, COSV58114157; called by muse, mutect2, varscan2
- CDON | c.2344G>A p.V782I | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1182235163, COSV54994616; called by muse, mutect2, varscan2
- CDX4 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.602); catalogued as COSV100999152, COSV65171389; called by muse, mutect2, varscan2
- CDYL | c.1625C>T p.S542L (on ENST00000328908 / NM_001368125.1; = p.S488L on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as rs370584550; called by muse, mutect2, varscan2
- CEL | c.139G>T p.G47C (on ENST00000673714; = p.G44C on NM_001807.6) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60826107; called by muse, varscan2
- CEL | c.2173G>C p.A725P (on ENST00000673714; = p.A722P on NM_001807.6) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.644); catalogued as rs202034862, COSV60826115, COSV60826621; called by muse, mutect2, varscan2
- CELF4 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV58445248; called by muse, mutect2, varscan2
- CELSR2 | c.3818G>A p.R1273H | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1249420698, COSV99603468; called by muse, mutect2, varscan2
- CELSR2 | c.4150C>T p.R1384C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286591349, COSV54765905; called by muse, mutect2, varscan2
- CELSR2 | c.6491C>T p.T2164M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775752921, COSV54765919; called by muse, mutect2, varscan2
- CENPC | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs369384820, COSV56620938; called by muse, mutect2, varscan2
- CENPJ | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs541232925, COSV67882826; called by muse, mutect2, varscan2
- CEP164 | c.2984A>C p.Q995P | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV99632899; called by muse, mutect2, varscan2
- CEP170B | c.1177C>T p.R393W (on ENST00000453495; = p.R322W on NM_015005.3) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773566048, COSV69022995; called by muse, mutect2, varscan2
- CEP192 | c.5989C>T p.R1997C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs746335630, COSV58059353; called by muse, mutect2, varscan2
- CEP192 | c.6347C>T p.A2116V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.155); catalogued as rs780513260, COSV58059364; called by muse, mutect2, varscan2
- CEP250 | c.3502G>A p.A1168T | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs781608093, COSV100698848; called by muse, mutect2, varscan2
- CEP68 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs774012835, COSV99560788; called by muse, mutect2, varscan2
- CEP89 | c.2278G>A p.V760I | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537113854, COSV99993297; called by muse, mutect2, varscan2
- CERK | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1443162838, COSV99348511; called by muse, mutect2, varscan2
- CFAP45 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141306445; called by muse, mutect2, varscan2
- CFAP45 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as COSV63647844; called by muse, mutect2, varscan2
- CFAP46 | c.8035T>C p.W2679R | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.044); catalogued as rs762673062, COSV54148021; called by muse, mutect2, varscan2
- CFAP46 | c.6940G>T p.G2314* | Nonsense Mutation (SNP) | VAF 25/85 reads (29%) | catalogued as COSV54148040; called by muse, mutect2, varscan2
- CFAP65 | c.4855C>T p.R1619* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | catalogued as rs765282879, COSV100444982, COSV58557378; called by muse, mutect2, varscan2
- CFAP69 | c.2061del p.K687Nfs*43 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | catalogued as rs1275710203; called by mutect2, pindel, varscan2
- CFHR4 | c.857G>A p.R286H (on ENST00000367416 / NM_001201551.2; = p.R287H on NM_001201550.3) | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.362); catalogued as rs188298928, COSV52223632, COSV99054624; called by muse, mutect2, varscan2
- CGB8 | c.438del p.S147Afs*? | Frame Shift Del (DEL) | VAF 29/136 reads (21%) | catalogued as COSV56822738; called by mutect2, pindel, varscan2
- CHAF1A | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs753582271, COSV56669738; called by muse, mutect2, varscan2
- CHAF1A | c.2233G>A p.G745S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56669761; called by muse, mutect2, varscan2
- CHAF1B | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58439050; called by muse, mutect2, varscan2
- CHD3 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV57872079; called by muse, mutect2, varscan2
- CHD4 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV58893592; called by muse, mutect2, varscan2
- CHD6 | c.2500C>T p.R834W | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58553262; called by muse, mutect2, varscan2
- CHDH | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59455592; called by muse, mutect2, varscan2
- CHFR | c.718G>A p.A240T (on ENST00000432561 / NM_001161345.1; = p.A199T on NM_018223.2) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs533118486, COSV99905155; called by muse, mutect2, varscan2
- CHI3L2 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs778552657, COSV63873224; called by muse, mutect2
- CHRNA10 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763121060, COSV51703869; called by muse, mutect2, varscan2
- CHRND | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs746959201, COSV99285637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57321555, COSV57324779; called by muse, mutect2, varscan2
- CHST12 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs149493991; called by muse, mutect2, varscan2
- CHST6 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59999304; called by muse, mutect2, varscan2
- CHSY1 | c.666del p.P223Lfs*3 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as rs762321510; called by mutect2, pindel, varscan2
- CIC | c.2492C>T p.T831M | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV50546523; called by muse, mutect2, varscan2
- CIITA | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs745446439, COSV60853463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CILK1 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs758321988, COSV63153199; called by muse, mutect2, varscan2
- CIP2A | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs151174833, COSV55416793; called by muse, mutect2, varscan2
- CKMT2 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1025098115, COSV54171986; called by muse, mutect2, varscan2
- CLCA4 | c.208dup p.R70Kfs*13 | Frame Shift Ins (INS) | VAF 63/357 reads (18%) | catalogued as rs148031684; called by mutect2, pindel, varscan2
- CLCN3 | c.2369G>A p.R790H | Missense Mutation (SNP) | VAF 75/413 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs771142045, COSV100641645; called by muse, mutect2, varscan2
- CLCN6 | c.213+1G>T p.X71_splice | Splice Site (SNP) | VAF 27/101 reads (27%) | catalogued as COSV56737615; called by muse, mutect2, varscan2
- CLDN10 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs1371711623, COSV54823063; called by muse, mutect2, varscan2
- CLIC6 | c.1910C>T p.T637M (on ENST00000360731 / NM_001317009.2; = p.T619M on NM_053277.3) | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141470374; called by muse, mutect2, varscan2
- CLK2 | c.399G>A p.S133= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as COSV62876375; called by muse, mutect2
- CLPTM1 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs548487634, COSV61610846; called by muse, mutect2, varscan2
- CLPTM1L | c.1595C>T p.T532M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs770025461, COSV57989090; called by muse, mutect2, varscan2
- CLUH | c.680C>A p.P227Q (on ENST00000435359; = p.P265Q on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70927513; called by muse, mutect2, varscan2
- CMTM5 | c.377del p.P126Rfs*55 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs751921758; called by mutect2, varscan2
- CNGA2 | c.13dup p.T5Nfs*11 | Frame Shift Ins (INS) | VAF 21/79 reads (27%) | catalogued as rs1033589039; called by mutect2, pindel, varscan2
- CNGA3 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as rs372215423; called by muse, mutect2, varscan2
- CNOT1 | c.3629T>A p.I1210N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV55312322; called by muse, mutect2, varscan2
- CNOT3 | c.732del p.S245Afs*90 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs753475896; called by mutect2, varscan2
- CNTLN | c.3601G>A p.V1201I | Missense Mutation (SNP) | VAF 96/369 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs568907262, COSV52064115; called by muse, mutect2, varscan2
- COBL | c.3282del p.K1094Nfs*20 | Frame Shift Del (DEL) | VAF 36/173 reads (21%) | catalogued as rs1562810271; called by mutect2, pindel, varscan2
- COG2 | c.1259A>G p.H420R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as rs898482785, COSV64185845; called by muse, mutect2, varscan2
- COG4 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV60420987; called by muse, varscan2
- COL13A1 | c.1195A>G p.K399E (on ENST00000398978 / NM_001130103.2; = p.K342E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100637386; called by muse, mutect2, varscan2
- COL18A1 | c.2788G>A p.V930I (on ENST00000359759 / NM_130444.3; = p.V695I on NM_030582.4) | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs1308231024, COSV62698109; called by muse, mutect2, varscan2
- COL1A1 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs139593707, COSV56810864; called by muse, varscan2
- COL1A1 | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99866817; called by muse, mutect2, varscan2
- COL4A1 | c.4967G>A p.R1656H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs756403856, COSV65420475; called by muse, mutect2, varscan2
- COL4A2 | c.1624G>A p.G542R | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64624242; called by muse, mutect2, varscan2
- COL5A1 | c.3319C>T p.P1107S | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV65668794; called by muse, mutect2, varscan2
- COL5A2 | c.2879G>C p.G960A | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66406601; called by muse, mutect2, varscan2
- COL6A3 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs372255458; called by muse, mutect2, varscan2
- COL6A3 | c.647G>A p.C216Y | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99797182; called by muse, mutect2, varscan2
- COL7A1 | c.7882C>T p.R2628W | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs376588113, CM107557; called by muse, mutect2, varscan2
- COL8A2 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.807); catalogued as rs759403098, COSV100291072; called by muse, mutect2, varscan2
- COL9A2 | c.1242del p.G415Efs*116 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | catalogued as rs756694568; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- CORIN | c.1921C>A p.P641T | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.804); catalogued as COSV56684912, COSV56689184; called by muse, varscan2
- COTL1 | c.401del p.G134Efs*48 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs1437232641; called by mutect2, varscan2
- CPA5 | c.505T>C p.F169L | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as COSV100812270; called by muse, mutect2, varscan2
- CPA6 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.406); catalogued as rs1018666393, COSV52719710, COSV52732409; called by muse, mutect2, varscan2
- CPAMD8 | c.450G>T p.W150C (on ENST00000651564; = p.W103C on NM_015692.5) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.922); catalogued as rs1341893022, COSV52230556, COSV52237430; called by muse, mutect2, varscan2
- CPSF6 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1331705563, COSV57011848; called by muse, mutect2, varscan2
- CPT1B | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as rs757184617, COSV56414818; called by muse, mutect2, varscan2
- CPT1C | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as rs995173040, COSV54917247; called by muse, mutect2, varscan2
- CRIM1 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.667); catalogued as rs1173656893, COSV54858684; called by muse, mutect2, varscan2
- CRLF3 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs774317573, COSV60835116; called by muse, mutect2, varscan2
- CRYBG1 | c.4813G>A p.A1605T | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs778430099, COSV64810258; called by muse, mutect2, varscan2
- CRYM | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs148349291, CM112951; called by muse, mutect2, varscan2
- CSMD1 | c.8506G>T p.G2836* (on ENST00000520002; = p.G2835* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 24/98 reads (24%) | catalogued as COSV59276382; called by muse, varscan2
- CSMD3 | c.9253G>T p.G3085C (on ENST00000297405 / NM_001363185.1; = p.G2916C on NM_052900.3) | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52090391; called by muse, mutect2, varscan2
- CTBP1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs764862588, COSV52071459; called by muse, mutect2, varscan2
- CTDP1 | c.1424A>G p.D475G | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs780184211, COSV99310341; called by muse, mutect2
- CTNNA3 | c.2568dup p.P857Tfs*4 | Frame Shift Ins (INS) | VAF 22/102 reads (22%) | catalogued as rs759618368; called by mutect2, varscan2
- CTNND1 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 28/103 reads (27%) | catalogued as COSV62381970; called by muse, mutect2, varscan2
- CTSA | c.307-2A>G p.X103_splice | Splice Site (SNP) | VAF 8/130 reads (6%) | catalogued as rs1438425045, COSV99509757; called by muse, mutect2
- CTSC | c.893G>A p.C298Y | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450551456, COSV99074360, COSV99910597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTSF | c.511A>G p.N171D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59747207; called by muse, mutect2, varscan2
- CWF19L2 | c.1398dup p.E467Rfs*17 | Frame Shift Ins (INS) | VAF 32/120 reads (27%) | catalogued as rs749288164; called by mutect2, varscan2
- CXADR | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV53027575; called by muse, mutect2, varscan2
- CXCL8 | c.260G>T p.R87M | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.424); catalogued as COSV100266221; called by muse, mutect2, varscan2
- CYB5D1 | c.620G>C p.S207T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54678015, COSV99641052; called by muse, mutect2, varscan2
- CYP1A1 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373568981; called by muse, mutect2, varscan2
- CYP1A2 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs201650099, COSV59658941; called by muse, mutect2, varscan2
- CYP2B6 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs138594605; called by muse, mutect2, varscan2
- CYP2S1 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs768581980, COSV100027404; called by muse, mutect2, varscan2
- CYP2S1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199534151, COSV59504869; called by muse, mutect2, varscan2
- CYP4A22 | c.1364+7C>T | Splice Region (SNP) | VAF 25/113 reads (22%) | catalogued as rs755535332, COSV53737743; called by muse, mutect2, varscan2
- CYP4F3 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV55406706; called by muse, mutect2, varscan2
- DAB1 | c.1385G>A p.R462H (on ENST00000371231; = p.R429H on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs144347021, COSV64692596; called by muse, mutect2, varscan2
- DACH1 | c.970A>G p.T324A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.358); catalogued as COSV100497977, COSV100498932; called by muse, mutect2, varscan2
- DACT1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV60019144; called by muse, mutect2, varscan2
- DACT1 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs147227144; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 33/107 reads (31%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DCAF4L1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.799); catalogued as rs1480842979, COSV60786280, COSV60786538; called by muse, mutect2, varscan2
- DCBLD1 | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs920955730, COSV99757426; called by muse, mutect2, varscan2
- DCP1A | c.1148A>G p.N383S | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV99587903; called by muse, mutect2, varscan2
- DCST1 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV55056095; called by muse, mutect2, varscan2
- DDHD2 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763476356, COSV68157058; called by muse, mutect2, varscan2
- DDX21 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); catalogued as rs200756197, COSV62555017; called by muse, mutect2, varscan2
- DDX23 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs1248155927, COSV57281805; called by muse, mutect2, varscan2
- DDX39B | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV66018368; called by muse, mutect2, varscan2
- DDX6 | c.369G>A p.Q123= | Splice Region (SNP) | VAF 48/235 reads (20%) | catalogued as COSV50587530; called by muse, mutect2, varscan2
- DEFA5 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs137962701; called by muse, mutect2, varscan2
- DENND5B | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs771022934, COSV60899270; called by muse, mutect2, varscan2
- DENR | c.323del p.K108Rfs*10 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | catalogued as rs1566061026; called by mutect2, pindel, varscan2
- DEPDC1 | c.1084A>G p.T362A | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV63957862, COSV63958922; called by muse, mutect2, varscan2
- DEPDC5 | c.2761C>T p.R921W (on ENST00000400246; = p.R990W on NM_014662.5) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs375050296; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DERL2 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as rs1159652396, COSV50146865; called by muse, mutect2, varscan2
- DGAT1 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367844653; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DHH | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs774203455, COSV57201246; called by muse, mutect2, varscan2
- DHX16 | c.2819G>A p.R940H | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773747627, COSV53312321; called by muse, mutect2, varscan2
- DHX33 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs767542929, COSV99834279; called by muse, mutect2, varscan2
- DIDO1 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV56612657; called by muse, mutect2, varscan2
- DIO3 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs370365050; called by muse, mutect2, varscan2
- DISP2 | c.4096C>T p.R1366* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs780263622, COSV99139818; called by muse, mutect2, varscan2
- DLC1 | c.2152G>A p.A718T (on ENST00000276297 / NM_001348081.2; = p.A281T on NM_006094.5) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV52288290; called by muse, varscan2
- DLC1 | c.1784G>A p.R595H (on ENST00000276297 / NM_001348081.2; = p.R158H on NM_006094.5) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1056583874, COSV52288302; called by muse, varscan2
- DLGAP4 | c.1768C>A p.L590M | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.996); catalogued as COSV59413840; called by muse, mutect2, varscan2
- DMAC2 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as rs1220005313, COSV55727125; called by muse, mutect2
- DMKN | c.1100A>C p.K367T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100303381; called by muse, mutect2, varscan2
- DMKN | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100303388; called by muse, mutect2
- DMRTB1 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.995); catalogued as rs1409581070, COSV101008273; called by muse, mutect2, varscan2
- DNAH1 | c.10682C>T p.P3561L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553642627, COSV70225849; called by muse, mutect2, varscan2
- DNAH1 | c.11051C>A p.A3684D | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV101325259; called by muse, mutect2, varscan2
- DNAH10 | c.9548C>T p.A3183V (on ENST00000409039; = p.A3122V on NM_207437.3) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs764908542, COSV68987130; called by muse, mutect2, varscan2
- DNAH10 | c.12905G>A p.R4302H (on ENST00000409039; = p.R4241H on NM_207437.3) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs775827104, COSV53018383; called by muse, mutect2, varscan2
- DNAH11 | c.1320dup p.L441Ifs*25 | Frame Shift Ins (INS) | VAF 28/118 reads (24%) | catalogued as rs1562668233; called by mutect2, varscan2
- DNAH17 | c.13148G>A p.R4383H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139023942; called by muse, mutect2
- DNAH5 | c.13757T>C p.I4586T | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as COSV99447515; called by muse, mutect2, varscan2
- DNAH5 | c.5927del p.G1976Efs*78 | Frame Shift Del (DEL) | VAF 36/106 reads (34%) | catalogued as rs1233412023, COSV54222791; called by pindel, varscan2
- DNAH6 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.021); catalogued as rs1263374947, COSV99405823; called by muse, mutect2, varscan2
- DNAH6 | c.4583G>A p.R1528Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599477, COSV52888451; called by muse, varscan2
- DNAH6 | c.5518C>T p.P1840S | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52847818; called by muse, mutect2, varscan2
- DNAH7 | c.1087T>C p.C363R | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100414549; called by muse, mutect2
- DNAH8 | c.7628G>A p.R2543Q | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs543347999, COSV100544145; called by muse, mutect2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | catalogued as rs774662919; called by mutect2, pindel, varscan2
- DNAJB2 | c.894del p.T299Pfs*54 | Frame Shift Del (DEL) | VAF 19/86 reads (22%) | catalogued as rs756369149; called by mutect2, pindel, varscan2
- DNAJB6 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs771003490, COSV51094092; called by muse, mutect2, varscan2
- DNAJC14 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV57911961; called by muse, mutect2, varscan2
- DNHD1 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs775587577, COSV54429409; called by muse, mutect2, varscan2
- DOCK11 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.557); catalogued as rs1174860954, COSV52232844; called by muse, mutect2, varscan2
- DOCK11 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV52232853; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOK4 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs757770307, COSV54671571; called by muse, mutect2, varscan2
- DOK5 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773975138, COSV52815822; called by muse, mutect2, varscan2
- DOK7 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs777057956, COSV100403256; called by muse, mutect2, varscan2
- DSCAM | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as COSV68019901; called by muse, mutect2, varscan2
- DSCAML1 | c.4785G>C p.E1595D (on ENST00000321322; = p.E1535D on NM_020693.4) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV58380100; called by muse, mutect2, varscan2
- DSCAML1 | c.1271G>A p.R424H (on ENST00000321322; = p.R364H on NM_020693.4) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs745820564, COSV58380111; called by muse, mutect2, varscan2
- DSCAML1 | c.1033C>T p.R345W (on ENST00000321322; = p.R285W on NM_020693.4) | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs868719705, COSV58390499; called by muse, mutect2, varscan2
- DSG2 | c.1943C>A p.P648H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55200004; called by mutect2, varscan2
- DSP | c.7702G>A p.G2568S | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs139486943; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTNB | c.1621G>A p.G541S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201535119, COSV56472069, COSV99977353; called by muse, mutect2, varscan2
- DTX4 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs376061897; called by muse, mutect2, varscan2
- DUOX1 | c.3484G>A p.V1162I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.031); catalogued as rs151144648; called by muse, mutect2, varscan2
- DVL3 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1290938231, COSV53046821; called by muse, mutect2, varscan2
- DYNC1H1 | c.3815G>A p.R1272H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV64133914; called by muse, mutect2, varscan2
- E2F3 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs138776759; called by muse, mutect2, varscan2
- ECHDC2 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764403275, COSV64299953; called by muse, mutect2, varscan2
- ECT2 | c.2605A>G p.S869G (on ENST00000392692 / NM_001349098.2; = p.S838G on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51686046; called by muse, mutect2
- EEF2K | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs143471765; called by muse, mutect2, varscan2
- EEPD1 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs764050568, COSV54195418; called by muse, mutect2, varscan2
- EFL1 | c.2242C>T p.L748F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs1358377910, COSV51602247; called by muse, mutect2, varscan2
- EGFL6 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs774377999, COSV63060143; called by muse, mutect2, varscan2
- EHD1 | c.741del p.E248Rfs*50 | Frame Shift Del (DEL) | VAF 22/136 reads (16%) | catalogued as rs774171970, COSV57737231; called by mutect2, pindel, varscan2
- EHD2 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757488835, COSV54406456; called by muse, mutect2, varscan2
- EHMT2 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV100977156; called by muse, mutect2, varscan2
- EID2B | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs753248992, COSV58318679; called by muse, mutect2, varscan2
- EIF2B3 | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV64516759; called by muse, mutect2, varscan2
- EIF3G | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.027); catalogued as rs767761417, COSV53458835, COSV99462442; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as rs762590530, COSV57514257; called by muse, mutect2, varscan2
- ELAVL3 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52950046, COSV52950601; called by muse, mutect2, varscan2
- ELAVL4 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV63913802; called by muse, mutect2, varscan2
- ELMO1 | c.2030T>C p.M677T | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV60293724; called by muse, mutect2
- ELOA | c.2344C>A p.P782T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69309269; called by muse, mutect2, varscan2
- EML2 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV55597185; called by muse, mutect2, varscan2
- ENAM | c.1372T>C p.W458R | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV101253002; called by muse, mutect2, varscan2
- ENGASE | c.1638del p.T547Pfs*14 | Frame Shift Del (DEL) | VAF 64/298 reads (21%) | catalogued as rs759157900, COSV56136050; called by mutect2, pindel, varscan2
- ENPP7 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs201532960; called by muse, mutect2, varscan2
- EPC1 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV53922700; called by muse, mutect2, varscan2
- EPC2 | c.1140G>T p.Q380H | Missense Mutation (SNP) | VAF 59/278 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV51539418; called by muse, mutect2, varscan2
- EPHA5 | c.2049A>G p.A683= | Splice Region (SNP) | VAF 24/126 reads (19%) | catalogued as COSV56627934; called by muse, mutect2, varscan2
- EPHB3 | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | catalogued as COSV100382928; called by muse, mutect2, varscan2
- EPPK1 | c.5030G>A p.G1677D | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73260687; called by muse, mutect2, varscan2
- EPPK1 | c.2082_2083insA p.Y695Ifs*68 | Frame Shift Ins (INS) | VAF 20/66 reads (30%) | catalogued as COSV73260694; called by mutect2, pindel, varscan2
- EPRS1 | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859347; called by muse, varscan2
- ERN2 | c.2332C>T p.H778Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1287500927, COSV55620174; called by muse, mutect2, varscan2
- ESR1 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866869178, COSV52780667; called by muse, mutect2
- ESRRG | c.590-1G>A p.X197_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | catalogued as COSV63148166; called by muse, mutect2, varscan2
- ETV3 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63864291; called by muse, mutect2, varscan2
- EVC2 | c.816+1G>A p.X272_splice | Splice Site (SNP) | VAF 14/58 reads (24%) | catalogued as COSV60387103, COSV60387151; called by muse, mutect2, varscan2
- EVI5 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 75/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752893341, COSV100789673, COSV63278771; called by muse, mutect2, varscan2
- EWSR1 | c.1483G>T p.G495* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV58421215; called by muse, mutect2, varscan2
- EXOC6 | c.465T>G p.Y155* | Nonsense Mutation (SNP) | VAF 12/268 reads (4%) | catalogued as COSV99591687; called by muse, mutect2
- EXPH5 | c.5303G>C p.S1768T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1188277966, COSV56198382, COSV99762411; called by muse, mutect2, varscan2
- F2 | c.43del p.L15Wfs*106 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as COSV61315759; called by mutect2, pindel, varscan2
- FADS2 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as COSV53896432; called by muse, mutect2, varscan2
- FAM135B | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99421597; called by muse, mutect2, varscan2
- FAM135B | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs779793997, COSV50521953, COSV99356912; called by muse, mutect2, varscan2
- FAM169A | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs778097956, COSV65845836; called by muse, varscan2
- FAM186B | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.092); catalogued as COSV57720235; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 48/216 reads (22%) | catalogued as rs768952789; called by mutect2, varscan2
- FAM200B | c.710G>T p.S237I | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV69958978; called by muse, mutect2, varscan2
- FAM20A | c.755_757del p.F252del | In Frame Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs768121766; called by pindel, varscan2
- FAM20B | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55379147; called by muse, mutect2, varscan2
- FAM214A | c.1255G>T p.G419* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV55921640; called by muse, mutect2, varscan2
- FAM222B | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV57926980; called by muse, mutect2, varscan2
- FAM47A | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs369143353, COSV60493587; called by muse, mutect2, varscan2
- FAM83B | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs759877272, COSV60918796; called by muse, mutect2, varscan2
- FAM83E | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs775093735, COSV52373976; called by muse, mutect2, varscan2
- FAM83H | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV101186951; called by muse, mutect2, varscan2
- FAM8A1 | c.1013T>A p.L338H | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99467485; called by muse, mutect2
- FAM98A | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV53208719; called by muse, mutect2, varscan2
- FARSA | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.163); catalogued as rs1424315717, COSV100108758; called by muse, mutect2, varscan2
- FASTK | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs1269749365, COSV99879662; called by muse, mutect2, varscan2
- FASTKD2 | c.164A>G p.H55R | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as COSV52697228; called by muse, mutect2, varscan2
- FAT1 | c.6743C>T p.P2248L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367776554; called by muse, mutect2, varscan2
- FAT3 | c.10615G>A p.V3539M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs531488417, COSV53070681, COSV53169706; called by muse, mutect2, varscan2
- FAT3 | c.11990C>T p.P3997L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1305076760, COSV53070707; called by muse, mutect2, varscan2
- FBF1 | c.2474G>A p.R825Q (on ENST00000586717; = p.R839Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as rs754215900, COSV100044693, COSV100044930; called by muse, varscan2
- FBN1 | c.5179C>T p.R1727W | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752450678, COSV57307989; called by muse, mutect2, varscan2
- FBN1 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV57308001; called by muse, mutect2, varscan2
- FBN2 | c.1697G>T p.R566M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.453); catalogued as COSV99326180; called by muse, mutect2, varscan2
- FBXL7 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.75); catalogued as rs550772953, COSV61649215; called by muse, mutect2, varscan2
- FBXO8 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.295); catalogued as rs760227265, COSV67031451; called by muse, mutect2, varscan2
- FBXW4 | c.1262G>A p.C421Y | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.159); catalogued as rs1420087169, COSV100489312; called by muse, mutect2
- FCAMR | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV61366553; called by muse, mutect2, varscan2
- FCGR2B | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV52680463; called by muse, mutect2, varscan2
- FCSK | c.2300G>A p.R767Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs572464313, COSV55367323; called by muse, mutect2, varscan2
- FER1L5 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as rs772718482, COSV70068285; called by muse, mutect2, varscan2
- FER1L5 | c.2975G>A p.R992H (on ENST00000623019; = p.R999H on NM_001293083.2) | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs985389957, COSV67605604; called by muse, mutect2, varscan2
- FER1L6 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs200724975, COSV67547680; called by muse, mutect2, varscan2
- FER1L6 | c.4714G>A p.V1572M | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV67547692; called by muse, mutect2, varscan2
- FERMT3 | c.1175A>G p.D392G (on ENST00000279227 / NM_178443.3; = p.D388G on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs542624473, COSV99656434; called by muse, mutect2, varscan2
- FFAR1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753588393, CM1511235, COSV50049490; called by muse, mutect2, varscan2
- FGA | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1276352833, CM082670, COSV57392315; called by muse, mutect2, varscan2
- FGD3 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775900978, COSV61595320; called by muse, mutect2, varscan2
- FGD5 | c.3940C>T p.R1314W | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs750545408, COSV53236523; called by muse, mutect2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 18/113 reads (16%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIG4 | c.2571A>T p.Q857H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57784566; called by muse, mutect2, varscan2
- FLG | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV64235543; called by muse, mutect2, varscan2
- FLNC | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs766755439, COSV100367735, COSV57954261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMO4 | c.817A>G p.I273V | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV63000528; called by muse, mutect2, varscan2
- FMO5 | c.407del p.K136Rfs*3 | Frame Shift Del (DEL) | VAF 23/81 reads (28%) | catalogued as COSV99567435; called by mutect2, pindel, varscan2
- FNDC1 | c.5351G>A p.R1784Q | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs747207185, COSV51929669; called by muse, mutect2, varscan2
- FOLH1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99922866; called by muse, mutect2, varscan2
- FOXA3 | c.146C>A p.P49H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100141301; called by muse, mutect2, varscan2
- FOXK1 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.166); catalogued as rs1299148388, COSV61064157; called by muse, mutect2, varscan2
- FOXL1 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV57213590; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs760347049; called by mutect2, pindel
- FOXR1 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV57652000; called by muse, mutect2
- FOXRED1 | c.1261G>A p.V421M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs199542988, CM0911501, COSV55004875; called by muse, mutect2, varscan2
- FOXRED2 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs764123276, COSV53398740, COSV99068177; called by muse, mutect2, varscan2
- FREM2 | c.4558C>T p.R1520W | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142322683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FREM2 | c.6197G>A p.R2066H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs370328796; called by muse, mutect2, varscan2
- FRYL | c.1714A>G p.M572V | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV51937858; called by muse, mutect2, varscan2
- FSCN3 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs747458889, COSV56171858; called by muse, mutect2, varscan2
- FSD1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs752149632, COSV55695904; called by muse, mutect2, varscan2
- FSD1 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs776511823, COSV55694251; called by muse, mutect2, varscan2
- FSD1L | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as rs1289314162, COSV65997026; called by muse, mutect2, varscan2
- FUT1 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV59567220; called by muse, mutect2, varscan2
- FUT8 | c.1322G>A p.R441Q (on ENST00000360689 / NM_001371534.1; = p.R278Q on NM_004480.4) | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs758856033, COSV61290251; called by mutect2, varscan2
- FYB2 | c.1851dup p.E618Rfs*6 | Frame Shift Ins (INS) | VAF 21/96 reads (22%) | catalogued as rs751048223; called by mutect2, varscan2
- FZD1 | c.1105T>C p.Y369H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as COSV55308666; called by muse, mutect2, varscan2
- FZD10 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV57471876; called by muse, mutect2, varscan2
- FZD2 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs1339183245, COSV59527929; called by muse, mutect2, varscan2
- FZD5 | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99776314; called by muse, mutect2
- FZD9 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.935); catalogued as COSV59988235; called by muse, mutect2, varscan2
- G3BP1 | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs372751446; called by muse, mutect2, varscan2
- GABPB2 | c.736G>T p.A246S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV64461609; called by muse, mutect2, varscan2
- GABRA5 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV100164945, COSV59482802; called by muse, mutect2, varscan2
- GADD45GIP1 | c.553_555del p.K185del | In Frame Del (DEL) | VAF 25/95 reads (26%) | catalogued as rs777674072; called by pindel, varscan2
- GAL3ST2 | c.941G>T p.R314M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99510854; called by muse, mutect2
- GALNT18 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs757382050, COSV57142838, COSV57151581; called by muse, mutect2, varscan2
- GALNT6 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.309); catalogued as COSV62541523; called by muse, mutect2, varscan2
- GALNT8 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as rs200878740, COSV52894184, COSV99362470; called by muse, mutect2, varscan2
- GALT | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD991725, CM012766, COSV58840113; called by muse, mutect2, varscan2
- GARNL3 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs756264516, COSV59223438; called by muse, mutect2, varscan2
- GATA4 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); catalogued as COSV58732194; called by muse, mutect2, varscan2
- GCK | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.753); catalogued as COSV56267101; called by muse, mutect2, varscan2
- GCN1 | c.7328G>A p.R2443H | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56102930; called by muse, mutect2, varscan2
- GDF5 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as COSV65499026; called by muse, mutect2, varscan2
- GGN | c.1613C>T p.T538I | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.206); catalogued as COSV53055820; called by muse, mutect2, varscan2
- GLIS2 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1287524266, COSV52109238; called by muse, mutect2, varscan2
- GMEB1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs960217167, COSV53792646; called by muse, mutect2, varscan2
- GMEB2 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99823556; called by muse, mutect2, varscan2
- GNAO1 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52609774; called by muse, mutect2, varscan2
- GNB1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV66099646; called by muse, varscan2
- GNB5 | c.1177-2A>C p.X393_splice (on ENST00000261837 / NM_016194.4; = p.X351_splice on NM_006578.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 15/89 reads (17%) | catalogued as COSV99953215; called by muse, mutect2, varscan2
- GNG11 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 52/244 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99949331; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GNPAT | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV64152908; called by muse, mutect2, varscan2
- GNS | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs767876998, COSV50693885; called by muse, mutect2, varscan2
- GOLGA3 | c.2122C>T p.R708* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99202529; called by muse, mutect2, varscan2
- GPA33 | c.698T>C p.M233T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769850908, COSV100900978; called by muse, mutect2, varscan2
- GPR12 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV67343949; called by muse, mutect2, varscan2
- GPR146 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs553378185, COSV52465325; called by muse, mutect2, varscan2
- GPR156 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs372902834; called by muse, mutect2
- GPR157 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV101072568; called by muse, mutect2, varscan2
- GPR158 | c.3193C>T p.R1065C | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs146528842; called by muse, mutect2, varscan2
- GPR88 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59290976; called by muse, mutect2, varscan2
- GPRC5C | c.1361G>A p.R454Q (on ENST00000652232; = p.R409Q on NM_018653.4) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (1); catalogued as rs144516528; called by muse, mutect2, varscan2
- GPT | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1416735347, COSV52952060; called by muse, mutect2, varscan2
- GRIK3 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as rs1023191275, COSV66134840; called by muse, mutect2, varscan2
- GRIN3A | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763643147, COSV62450884, COSV62455791, COSV62458539; called by muse, mutect2, varscan2
- GRIP1 | c.2601G>A p.W867* (on ENST00000359742 / NM_001379345.1; = p.W815* on NM_021150.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 37/118 reads (31%) | catalogued as COSV54014232, COSV54029171; called by muse, mutect2, varscan2
- GRK2 | c.1748T>C p.L583P | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100398407; called by muse, mutect2, varscan2
- GSDMC | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs550446533, COSV52694107; called by mutect2, varscan2
- GSE1 | c.2729C>T p.P910L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1443176629, COSV53669078, COSV53675356; called by muse, mutect2, varscan2
- GSK3A | c.998T>C p.I333T | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99725170; called by muse, mutect2, varscan2
- GSPT1 | c.727C>T p.P243S (on ENST00000420576 / NM_001130007.2; = p.P381S on NM_002094.4) | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV70452358; called by muse, mutect2, varscan2
- GZF1 | c.1185del p.H395Qfs*22 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as COSV57634509; called by mutect2, pindel, varscan2
- H1-8 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs149670868; called by muse, mutect2, varscan2
- H3C2 | c.346A>G p.K116E | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.049); catalogued as COSV52518577; called by muse, mutect2, varscan2
- HABP4 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 22/106 reads (21%) | catalogued as rs1420051493, COSV64514560; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HDAC4 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs371367857; called by muse, varscan2
- HDAC9 | c.2218A>G p.T740A | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67765491; called by muse, mutect2, varscan2
- HDLBP | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.273); catalogued as COSV60491559; called by muse, mutect2, varscan2
- HEATR5A | c.3970-1G>A p.X1324_splice | Splice Site (SNP) | VAF 8/56 reads (14%) | catalogued as COSV66338105; called by muse, mutect2, varscan2
- HEG1 | c.4132_4134del p.R1378del | In Frame Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs764062830; called by pindel, varscan2
- HEMK1 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs779386497, COSV51749749, COSV99231756; called by muse, mutect2, varscan2
- HENMT1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV64229882; called by muse, mutect2, varscan2
- HEPACAM2 | c.554del p.N185Mfs*25 (on ENST00000394468 / NM_001039372.4; = p.N173Mfs*25 on NM_198151.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 32/161 reads (20%) | catalogued as COSV59062549; called by pindel, varscan2
- HERC2 | c.12523G>A p.G4175S | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55305110; called by muse, mutect2, varscan2
- HERC2 | c.8000G>A p.G2667E | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55305121; called by muse, mutect2, varscan2
- HERC2 | c.2740T>C p.C914R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs1486071125, COSV99872296; called by muse, mutect2, varscan2
- HEYL | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs747977443, COSV65721306; called by muse, mutect2, varscan2
- HFE | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as rs28934889, CM994469; ClinVar: benign; called by muse, mutect2, varscan2
- HHAT | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs143700139; called by muse, mutect2, varscan2
- HHIP | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs146905204; called by muse, mutect2, varscan2
- HID1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.529); catalogued as rs777264298, COSV59350919; called by muse, mutect2, varscan2
- HINT3 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV57649260; called by muse, mutect2, varscan2
- HKDC1 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.59); catalogued as rs776482675, COSV63575278; called by muse, mutect2, varscan2
- HMGXB3 | c.2914G>A p.V972M (on ENST00000613459; = p.V726M on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs753841260, COSV72211447; called by muse, mutect2, varscan2
- HMX2 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV100378709, COSV60593326; called by muse, mutect2
- HNRNPA0 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100152888; called by muse, mutect2, varscan2
- HOATZ | c.62del p.P21Rfs*79 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | catalogued as rs570525399; called by mutect2, pindel, varscan2
- HORMAD2 | c.677G>A p.G226D | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.102); catalogued as COSV100374092; called by muse, mutect2, varscan2
- HOXA3 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1347019202; called by muse, mutect2
- HOXB4 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1408525482, COSV100203708; called by muse, mutect2
- HRAS | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs1473091760, COSV99529808; called by muse, mutect2, varscan2
- HRH1 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs138501310, COSV67954997; called by muse, mutect2, varscan2
- HS3ST1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50022953; called by muse, mutect2, varscan2
- HSCB | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV53261835; called by muse, mutect2, varscan2
- HSD17B14 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.017); catalogued as rs760796044, COSV54414915; called by muse, mutect2, varscan2
- HSD17B2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752344353, COSV52274074; called by muse, mutect2, varscan2
- HSPBAP1 | c.1318A>G p.S440G | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100063321; called by muse, mutect2, varscan2
- HTT | c.3527del p.P1176Lfs*3 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs1457514406; called by mutect2, pindel, varscan2
- IER2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52847511; called by muse, mutect2, varscan2
- IFT43 | c.605C>T p.A202V (on ENST00000314067 / NM_001102564.3; = p.A207V on NM_052873.3) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.007); catalogued as rs764790125, COSV53136346; called by muse, mutect2
- IGDCC3 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs754726071, COSV60076221, COSV60078105; called by muse, mutect2, varscan2
- IGF2R | c.3582G>A p.S1194= | Splice Region (SNP) | VAF 8/53 reads (15%) | catalogued as COSV63625931; called by muse, mutect2, varscan2
- IGFALS | c.964G>T p.G322C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV51904404; called by muse, mutect2, varscan2
- IGHV1-46 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.283); catalogued as rs781917710; called by muse, mutect2, varscan2
- IGKV1-5 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs539543138; called by muse, mutect2, varscan2
- IGLV2-18 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.387); catalogued as rs745328084; called by muse, mutect2, varscan2
- IL17RA | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.536); catalogued as rs151220068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL18R1 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs758012132, COSV52126847; called by muse, mutect2, varscan2
- IL24 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as rs551792796, COSV54319868; called by muse, mutect2, varscan2
- IL2RG | c.1082del p.P361Hfs*5 | Frame Shift Del (DEL) | VAF 29/63 reads (46%) | catalogued as rs745545309; called by mutect2, pindel, varscan2
- ILDR2 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as rs754861502, COSV54828128; called by muse, mutect2, varscan2
- IMMP2L | c.156del p.S53Afs*9 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | catalogued as rs764675061; called by mutect2, pindel, varscan2
- IMP3 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs543082666, COSV59188818; called by muse, mutect2, varscan2
- INCENP | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs768284528, COSV53912829; called by muse, mutect2, varscan2
- INF2 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1482020773, COSV57976472; called by muse, mutect2
- INF2 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs769598010, COSV53029218; called by muse, mutect2, varscan2
- ING4 | c.398G>A p.R133Q (on ENST00000396807 / NM_001127582.2; = p.R132Q on NM_016162.4) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as rs374663258; called by muse, mutect2, varscan2
- INKA1 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760737503, COSV58525719; called by muse, mutect2, varscan2
- INKA2 | c.825del p.T276Qfs*25 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | catalogued as rs759002690; called by mutect2, pindel, varscan2
- INPP5D | c.1963G>A p.A655T (on ENST00000445964 / NM_001017915.3; = p.A654T on NM_005541.5) | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as rs756001826, COSV64035173; called by muse, mutect2, varscan2
- INPP5F | c.1050T>C p.S350= | Splice Region (SNP) | VAF 20/103 reads (19%) | catalogued as COSV100740059; called by muse, mutect2, varscan2
- INPPL1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs774794017, COSV53352894; called by muse, mutect2, varscan2
- INSM2 | c.1605dup p.S536* | Frame Shift Ins (INS) | VAF 22/79 reads (28%) | catalogued as rs756928018; called by mutect2, varscan2
- IP6K2 | c.1266G>T p.E422D | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV53659457; called by muse, mutect2, varscan2
- IQCC | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs748442077, COSV52207185; called by muse, mutect2, varscan2
- IQGAP3 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs749747273, COSV63248859, COSV63251190; called by muse, mutect2, varscan2
- IRS1 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1372054385, COSV59337994; called by muse, mutect2, varscan2
- IRS2 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1263611702, COSV101018950; called by muse, mutect2
- IRX1 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV57357680, COSV57360953; called by muse, mutect2, varscan2
- ISYNA1 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs772915404, COSV54209084; called by muse, mutect2, varscan2
- ITGAM | c.1964G>A p.C655Y (on ENST00000648685 / NM_001145808.2; = p.C654Y on NM_000632.4) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54933088; called by muse, mutect2, varscan2
- ITGB6 | c.1320_1321insT p.G441Wfs*51 | Frame Shift Ins (INS) | VAF 8/55 reads (15%) | catalogued as COSV51790343; called by mutect2, varscan2
- ITK | c.941A>T p.D314V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV68435204; called by muse, mutect2, varscan2
- ITPA | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as rs142979373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITPKA | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53027230, COSV99540722; called by muse, mutect2, varscan2
- ITPR1 | c.2782G>A p.V928M (on ENST00000354582; = p.V913M on NM_002222.7) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs751172849, COSV56966167; called by muse, mutect2, varscan2
- ITPRIP | c.383dup p.A129Rfs*19 | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | catalogued as rs751596276; called by mutect2, pindel
- IVD | c.1051G>A p.D351N (on ENST00000651168; = p.D348N on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs374930693; called by muse, mutect2, varscan2
- IWS1 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54866229; called by muse, mutect2, varscan2
- JAKMIP2 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54596644; called by muse, mutect2, varscan2
- JARID2 | c.3287G>A p.R1096H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs772155471, COSV59184531; called by muse, mutect2, varscan2
- JAZF1 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs1236026612, COSV52231909; called by muse, mutect2, varscan2
- JMJD1C | c.3134A>T p.E1045V | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as COSV59514430; called by muse, mutect2, varscan2
- JPH4 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1474125158, COSV62508011; called by muse, mutect2, varscan2
- KANSL1 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1258391982, COSV52264523; called by muse, mutect2, varscan2
- KAT2B | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV55425907; called by muse, mutect2, varscan2
- KAT6A | c.4351G>C p.A1451P | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV99704765; called by muse, mutect2, varscan2
- KAT8 | c.708dup p.G237Rfs*16 | Frame Shift Ins (INS) | VAF 11/49 reads (22%) | catalogued as rs773168027; called by mutect2, pindel, varscan2
- KATNIP | c.2735del p.G912Dfs*85 | Frame Shift Del (DEL) | VAF 30/79 reads (38%) | catalogued as COSV99850113; called by mutect2, varscan2
- KAZN | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV101055209; called by muse, mutect2
- KCNA1 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748830362, COSV66836386; called by muse, mutect2, varscan2
- KCNA3 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV63900814; called by muse, mutect2, varscan2
- KCNA5 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV52903591; called by muse, mutect2, varscan2
- KCNB1 | c.1018A>G p.M340V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.579); catalogued as COSV100870427, COSV100870587; called by muse, mutect2, varscan2
- KCND1 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as COSV54412164; called by muse, mutect2, varscan2
- KCND3 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56186607; called by muse, mutect2
- KCNG2 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs780887506, COSV60266517; called by muse, mutect2, varscan2
- KCNH1 | c.328T>G p.F110V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.145); catalogued as COSV99658323; called by muse, mutect2
- KCNH1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.157); catalogued as COSV55067296, COSV55077867; called by muse, mutect2, varscan2
- KCNJ8 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.991); catalogued as COSV53715616; called by muse, mutect2, varscan2
- KCNK6 | c.938G>T p.R313M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99649320; called by muse, mutect2, varscan2
- KCNN3 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769288919, COSV55211748; called by muse, mutect2, varscan2
- KCP | c.4379G>A p.C1460Y (on ENST00000620378; = p.C1584Y on NM_001366122.1) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99925914; called by muse, mutect2, varscan2
- KCTD9 | c.461A>G p.H154R | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV55338983; called by muse, mutect2, varscan2
- KDM2A | c.3133C>T p.R1045W | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV58188301; called by muse, mutect2, varscan2
- KDM2B | c.77del p.K26Rfs*81 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs782541016; called by mutect2, pindel, varscan2
- KDM3B | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as COSV58687357; called by muse, mutect2, varscan2
- KDM4B | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV50208384; called by muse, mutect2, varscan2
- KDM8 | c.844-1G>T p.X282_splice | Splice Site (SNP) | VAF 20/88 reads (23%) | catalogued as COSV53728142; called by muse, mutect2, varscan2
- KHDC3L | c.134T>A p.V45D | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100951082; called by muse, mutect2, varscan2
- KIAA1549L | c.2575C>T p.R859W (on ENST00000321505; = p.R1156W on NM_012194.3) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1247934271, COSV55768925; called by muse, mutect2, varscan2
- KIAA1958 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV61721203; called by muse, mutect2, varscan2
- KIF13A | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52441312; called by muse, mutect2, varscan2
- KIF1A | c.2344del p.R782Afs*30 | Frame Shift Del (DEL) | VAF 37/129 reads (29%) | catalogued as COSV57494105, COSV57504132; called by mutect2, pindel, varscan2
- KIF21A | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765082569, COSV62766537; called by muse, mutect2, varscan2
- KIF26A | c.2557G>A p.G853S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs529315066, COSV100180990; called by muse, mutect2, varscan2
- KIF26B | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs371419440; called by muse, mutect2, varscan2
- KIF3A | c.1792C>T p.R598W | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs768023298, COSV66412750; called by muse, mutect2, varscan2
- KIF5A | c.2671C>T p.R891C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV54051316; called by muse, mutect2, varscan2
- KIF5B | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs377656602; called by muse, mutect2, varscan2
- KIRREL2 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs1327248126, COSV52873993; called by muse, mutect2, varscan2
- KIRREL3 | c.1260del p.I421Sfs*63 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as rs753746325; called by mutect2, pindel, varscan2
- KLC3 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs773481222, COSV67279990; called by muse, mutect2, varscan2
- KLHDC2 | c.739T>A p.Y247N | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV53586410; called by muse, mutect2, varscan2
- KLHDC4 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.892); catalogued as COSV54505713; called by muse, mutect2, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | catalogued as rs749011008; called by mutect2, pindel
- KLHL15 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60139780; called by muse, mutect2, varscan2
- KLHL26 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs762413416, COSV56318597; called by muse, mutect2, varscan2
- KLHL29 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs980074844, COSV72085124; called by muse, mutect2, varscan2
- KLHL4 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs1325990722, COSV64138597; called by muse, mutect2, varscan2
- KMT2C | c.6416G>A p.R2139Q | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1400133609, COSV51274419; called by muse, mutect2, varscan2
- KMT2D | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.089); catalogued as rs377761041; called by muse, mutect2, varscan2
- KPNA7 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.874); catalogued as COSV59396752; called by muse, mutect2, varscan2
- KRR1 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs375387200; called by muse, mutect2, varscan2
- KRT16 | c.197del p.G66Afs*54 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs1555573913; called by mutect2, pindel, varscan2
- KRT2 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs144860513; called by muse, mutect2, varscan2
- KRT35 | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV55842183, COSV55844584; called by muse, mutect2, varscan2
- KRT37 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs375440985; called by muse, mutect2, varscan2
- KRT79 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs775879705, COSV57938097, COSV57938701; called by muse, mutect2, varscan2
- KRT81 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs542019661, COSV59811594; called by muse, varscan2
- KRT82 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs185048433, CM142463; called by muse, mutect2, varscan2
- KRT86 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1169609517, COSV53292210, COSV53292833; called by muse, mutect2, varscan2
- KRT86 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs534973333, COSV53291260; called by muse, mutect2, varscan2
- KRTAP10-11 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369473800; called by muse, mutect2, varscan2
- KRTAP10-5 | c.90del p.C31Afs*7 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as rs782662409; called by mutect2, pindel, varscan2
- KRTAP17-1 | c.86G>A p.C29Y | Missense Mutation (SNP) | VAF 11/48 reads (23%) | PolyPhen probably damaging (0.991); catalogued as COSV61971873; called by muse, mutect2, varscan2
- LAMA2 | c.5284C>T p.R1762W | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs746492572, COSV70342198; called by muse, mutect2, varscan2
- LAMA2 | c.8625del p.A2876Pfs*27 | Frame Shift Del (DEL) | VAF 34/215 reads (16%) | catalogued as COSV70352979; called by mutect2, pindel, varscan2
- LAMA5 | c.9466G>A p.A3156T | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140550546; called by muse, mutect2, varscan2
- LBR | c.456A>T p.K152N | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV99687290; called by muse, mutect2
- LCP1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs755322384, COSV59940540; called by muse, varscan2
1,798 further variants in this file (1,089 protein-altering or splice-affecting, 530 silent, 179 other) are not listed here.
